Somatic mutation profile of tumor specimen MP2PRT-PAVJSX-TMP1-A (aliquot MP2PRT-PAVJSX-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVJSX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,317 days).
Specimen MP2PRT-PAVJSX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fb63a29-2acb-4e03-848e-a2f453ed0637.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJSX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJSX-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/feeda73a-f59a-4e02-9a29-2e8ccc0d4dfc

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 16, Nonsense Mutation 3, Splice Region 1, Intron 1, Frame Shift Ins 1, In Frame Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX5 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 50/877 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs767260151; called by muse, mutect2
- CDCP2 | c.104C>G p.S35* | Nonsense Mutation (SNP) | VAF 24/298 reads (8%) | catalogued as COSV61286391; called by muse, mutect2
- CRYGA | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 186/550 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1474537753, COSV58015164; called by muse, mutect2, varscan2
- CSK | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs754118184, COSV54973937; called by muse, mutect2
- DSCAM | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 42/618 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV101260774; called by muse, mutect2
- ENPP6 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 34/573 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745885904, COSV57068180; called by muse, mutect2
- KIFAP3 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.626); catalogued as COSV100847011; called by muse, mutect2
- MYH4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 144/496 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs755708452, COSV55113074; called by muse, mutect2, varscan2
- MYH7B | c.5302-1G>A p.X1768_splice | Splice Site (SNP) | VAF 88/318 reads (28%) | catalogued as rs1465089882; called by muse, varscan2
- MYH7B | c.5536G>A p.E1846K | Missense Mutation (SNP) | VAF 72/596 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs998335057; called by muse, varscan2
- MYH7B | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 52/410 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438801397; called by muse, varscan2
- MYH7B | c.5863G>C p.E1955Q | Missense Mutation (SNP) | VAF 96/616 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV52680991; called by muse, mutect2, varscan2
- NBEA | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1229774400; called by muse, mutect2, varscan2
- STEAP3 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 112/685 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs760800930; called by muse, mutect2, varscan2
- SYNE1 | c.4987G>C p.E1663Q (on ENST00000367255 / NM_182961.4; = p.E1670Q on NM_033071.3) | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV54971693; called by muse, mutect2, varscan2
- WDR86 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 199/558 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.387); catalogued as COSV57838067; called by muse, mutect2, varscan2
- ANAPC2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 19/687 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ATG2A | c.82T>A p.F28I | Missense Mutation (SNP) | VAF 188/496 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- BMX | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 141/517 reads (27%) | called by muse, mutect2, varscan2
- CDC16 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DAAM1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2
- DCAF8L2 | c.1068del p.V357Lfs*3 | Frame Shift Del (DEL) | VAF 133/540 reads (25%) | called by mutect2, pindel, varscan2
- DEPDC5 | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.3499G>C p.E1167Q | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- DSEL | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- EFHC1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- EPHB3 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 85/633 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FAXC | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 203/559 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FSIP2 | c.15832G>A p.E5278K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- GIMAP4 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 193/483 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GPRASP2 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 196/883 reads (22%) | called by muse, mutect2, varscan2
- JAG1 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LFNG | c.931_932delinsCCCTTGGGGGC p.F311delinsPLGA (on ENST00000222725 / NM_001040167.2; = p.F182delinsPLGA on NM_002304.2) | In Frame Ins (INS) | VAF 185/650 reads (28%) | called by pindel, varscan2*
- LZTR1 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 145/383 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL19 | c.220A>C p.R74= | Splice Region (SNP) | VAF 138/382 reads (36%) | called by muse, mutect2, varscan2
- MYH7B | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 122/888 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- MYH7B | c.5194G>A p.E1732K | Missense Mutation (SNP) | VAF 236/762 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAIP1 | c.1234_1235insACCC p.F412Yfs*6 | Frame Shift Ins (INS) | VAF 19/158 reads (12%) | called by pindel, varscan2
- PCNX2 | c.3258G>C p.K1086N | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- PSMC6 | c.465G>C p.Q155H (on ENST00000612399; = p.Q141H on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PTPN3 | c.401T>A p.I134N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- RGS14 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 108/665 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RIMS1 | c.2998C>G p.P1000A | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- RSBN1L | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TRPC4AP | c.2335C>T p.L779F | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- WNK1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AVIL | c.657G>C p.L219= | Silent (SNP) | VAF 156/516 reads (30%) | catalogued as COSV57681733; called by muse, mutect2, varscan2
- CD22 | c.1869C>T p.P623= | Silent (SNP) | VAF 246/684 reads (36%) | catalogued as rs766386069; called by muse, mutect2, varscan2
- CDH24 | c.2459G>A p.*820= | Silent (SNP) | VAF 66/504 reads (13%) | catalogued as rs1415552481; called by muse, mutect2, varscan2
- CDH4 | c.201G>C p.G67= | Silent (SNP) | VAF 113/330 reads (34%) | catalogued as rs548726503; called by muse, mutect2, varscan2
- COL2A1 | c.2499G>A p.A833= | Silent (SNP) | VAF 176/510 reads (35%) | catalogued as rs779244918; ClinVar: likely benign; called by muse, mutect2, varscan2
- DEPDC5 | c.1068G>A p.R356= | Silent (SNP) | VAF 49/365 reads (13%) | catalogued as COSV99835254; called by muse, mutect2, varscan2
- EGFLAM | c.288C>T p.T96= | Silent (SNP) | VAF 61/326 reads (19%) | catalogued as rs1293724680, COSV59314093; called by muse, mutect2, varscan2
- FOXN3 | c.411G>A p.V137= | Silent (SNP) | VAF 53/588 reads (9%) | called by muse, mutect2
- KCNV2 | c.678C>T p.V226= | Silent (SNP) | VAF 239/711 reads (34%) | catalogued as rs767223506, COSV101172504; called by muse, mutect2, varscan2
- KREMEN1 | c.1374C>G p.L458= (on ENST00000407188; = p.L460= on NM_032045.5) | Silent (SNP) | VAF 45/314 reads (14%) | catalogued as rs765989334; called by muse, mutect2, varscan2
- NLGN4X | c.1794C>T p.H598= | Silent (SNP) | VAF 38/324 reads (12%) | called by muse, mutect2
- NLGN4Y | c.1794C>T p.H598= | Silent (SNP) | VAF 203/409 reads (50%) | called by muse, mutect2, varscan2
- NOA1 | c.1737G>A p.Q579= | Silent (SNP) | VAF 97/303 reads (32%) | called by muse, mutect2, varscan2
- TRPC4AP | c.2007C>A p.L669= | Silent (SNP) | VAF 43/327 reads (13%) | called by muse, mutect2, varscan2
- WDR86 | c.333C>T p.F111= | Silent (SNP) | VAF 147/405 reads (36%) | called by muse, mutect2, varscan2
- WLS | c.615G>A p.E205= | Silent (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10361-4577C>T | Intron (SNP) | VAF 78/202 reads (39%) | called by muse, mutect2, varscan2
